Somatic mutation profile of tumor specimen TARGET-30-PATBMM-01A (aliquot TARGET-30-PATBMM-01A-01D) from TARGET case TARGET-30-PATBMM, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.0 years (1,112 days).
Specimen TARGET-30-PATBMM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 358e5c2b-71c5-4e56-b7e2-603e2ad9227c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATBMM-10A (Blood Derived Normal), aliquot TARGET-30-PATBMM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de98700b-a5e3-430f-9c35-366f6444047f

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP1 | c.2424C>A p.F808L | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV60528938; called by muse, mutect2, varscan2
- CR2 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as COSV65506456; called by muse, mutect2, varscan2
- DCAKD | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1436839194, COSV60201854; called by muse, mutect2, varscan2
- FAT2 | c.12652G>A p.E4218K | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV55815558; called by muse, mutect2, varscan2
- LAMC2 | c.1409G>T p.C470F | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV51453407; called by muse, mutect2, varscan2
- NAT2 | c.493A>T p.R165W | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54061474; called by muse, mutect2, varscan2
- RAB11B | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV60085384; called by muse, mutect2, varscan2
- RPS2 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51909619; called by muse, mutect2
- RSL1D1 | c.1060C>A p.Q354K | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV63077540; called by muse, mutect2, varscan2
- TMPRSS11F | c.1159-1G>T p.X387_splice | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100678149; called by muse, mutect2, varscan2
- TRPV5 | c.854C>A p.S285Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54683843, COSV54683883; called by muse, mutect2, varscan2
- UNC79 | c.2978G>T p.R993I (on ENST00000393151 / NM_001346218.2; = p.R816I on NM_020818.5) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.088); catalogued as COSV56379039; called by muse, mutect2, varscan2
- YARS1 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65113281; called by muse, mutect2, varscan2
- ZNF556 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV56911299; called by muse, varscan2
- ABCA13 | c.14665C>A p.P4889T | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR14K1 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- AMACR | c.729G>T p.L243= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV59460224; called by muse, mutect2, varscan2
- DKK1 | c.300C>A p.P100= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV64760056; called by muse, mutect2, varscan2
- LILRA1 | c.591C>T p.C197= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV52177749; called by muse, mutect2
- MUC16 | c.36894G>T p.V12298= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV67453133; called by muse, mutect2, varscan2
- OR5W2 | c.261C>A p.A87= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.501G>T p.L167= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV53908029; called by muse, mutect2, varscan2
- RNF213 | c.13116G>T p.L4372= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV60392787; called by muse, mutect2, varscan2
- SLC48A1 | c.*97C>A | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
